Somatic mutation profile of tumor specimen C3L-02625-04 (aliquot CPT0191710006) from CPTAC case C3L-02625, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 66.2 years (24,167 days).
Specimen C3L-02625-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02303672-ad16-4270-b612-b2256c8cb969.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02625-32 (Blood Derived Normal), aliquot CPT0191850005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f442287b-6324-43d1-882d-2067fdde440b

The open-access MAF lists 467 somatic variants for this specimen: 297 protein-altering or splice-affecting, 109 silent, 61 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 258, Silent 109, Intron 34, Nonsense Mutation 23, RNA 11, 5'UTR 8, 3'UTR 7, Frame Shift Del 7, Splice Site 2, Frame Shift Ins 2, Splice Region 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 144/780 reads (18%) | hotspot (GDC flag); catalogued as rs121913384, CM034218, CM095540, COSV58683071, COSV58683670; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1010G>T p.R337L | Missense Mutation (SNP) | VAF 42/300 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs121912664, CM012663, CM104660, COSV52665150, COSV52691988, COSV52828545; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.2983C>T p.R995W | Missense Mutation (SNP) | VAF 32/312 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs761021001, COSV62321722; called by muse, mutect2, varscan2
- ADAM22 | c.311T>A p.V104D | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV55980410; called by muse, mutect2, varscan2
- ADAMTS20 | c.4568G>T p.R1523M | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs1308764332; called by muse, mutect2, varscan2
- ADAMTS20 | c.4079C>A p.P1360Q | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67139931; called by muse, mutect2, varscan2
- ANKRD20A2P | c.133G>T p.D45Y | Missense Mutation (SNP) | VAF 59/583 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV66464271; called by mutect2, varscan2
- AR | c.1705G>T p.G569W | Missense Mutation (SNP) | VAF 71/215 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555982864, CM942023, COSV101018580, COSV65965227; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARFGAP1 | c.917C>G p.S306W | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs369195697; called by muse, varscan2
- ATG14 | c.745C>T p.R249* | Nonsense Mutation (SNP) | VAF 89/477 reads (19%) | catalogued as COSV55955465, COSV55958773; called by muse, mutect2, varscan2
- BIRC6 | c.10979C>T p.S3660F | Missense Mutation (SNP) | VAF 75/550 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs145493127; called by muse, mutect2, varscan2
- C7 | c.2464G>T p.A822S | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.058); catalogued as COSV57474906; called by muse, mutect2, varscan2
- CACNA1C | c.928G>T p.E310* | Nonsense Mutation (SNP) | VAF 40/303 reads (13%) | catalogued as rs1555671961; called by muse, mutect2, varscan2
- CDO1 | c.486T>A p.D162E | Missense Mutation (SNP) | VAF 38/280 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV51666012; called by muse, mutect2, varscan2
- CHD9 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 36/260 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.971); catalogued as COSV101272150; called by muse, mutect2, varscan2
- CHRM1 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 50/352 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV61006407; called by muse, mutect2, varscan2
- CNTN5 | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 55/347 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as COSV54330503; called by muse, mutect2, varscan2
- COL4A2 | c.2842G>A p.E948K | Missense Mutation (SNP) | VAF 41/196 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.49); catalogued as rs199678709; called by muse, mutect2, varscan2
- DCAF8L2 | c.1788G>T p.W596C | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.893); catalogued as COSV70551242; called by muse, mutect2, varscan2
- DDX42 | c.883G>T p.G295C | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63789791; called by muse, mutect2, varscan2
- DNAH17 | c.7115G>A p.R2372Q | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as rs780980042, COSV101102805; called by muse, mutect2
- DNAH7 | c.6628C>A p.H2210N | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56778551; called by muse, mutect2
- DOK7 | c.557C>A p.S186* | Nonsense Mutation (SNP) | VAF 17/83 reads (20%) | catalogued as COSV60773003; called by muse, mutect2, varscan2
- DSCAM | c.4067A>G p.Y1356C | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as rs879128271, COSV101259158; called by muse, mutect2, varscan2
- DYRK4 | c.783A>G p.V261= | Splice Region (SNP) | VAF 15/94 reads (16%) | catalogued as rs1261902133; called by muse, mutect2, varscan2
- EFHC1 | c.710C>T p.T237I | Missense Mutation (SNP) | VAF 28/354 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.261); catalogued as rs765821468; called by muse, mutect2
- ERBB4 | c.628A>G p.R210G | Missense Mutation (SNP) | VAF 58/452 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs1209788009; called by muse, mutect2, varscan2
- F13B | c.1648G>T p.E550* | Nonsense Mutation (SNP) | VAF 12/123 reads (10%) | catalogued as COSV100803352; called by muse, mutect2
- FAT2 | c.9893C>T p.S3298F | Missense Mutation (SNP) | VAF 67/431 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV55830182; called by muse, mutect2, varscan2
- FBN2 | c.4244G>A p.G1415E | Missense Mutation (SNP) | VAF 63/455 reads (14%) | SIFT tolerated (0.98); PolyPhen benign (0.044); catalogued as COSV52521932; called by muse, mutect2, varscan2
- FCRL2 | c.991T>A p.L331M | Missense Mutation (SNP) | VAF 38/317 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV63833914; called by muse, mutect2, varscan2
- FCRL4 | c.607A>G p.T203A | Missense Mutation (SNP) | VAF 61/267 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.719); catalogued as COSV99620105; called by muse, mutect2, varscan2
- FMN2 | c.530C>A p.S177* | Nonsense Mutation (SNP) | VAF 56/494 reads (11%) | catalogued as COSV60451212; called by muse, mutect2, varscan2
- GIMAP1 | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.737); catalogued as COSV100211979; called by muse, mutect2, varscan2
- GINS2 | c.78C>G p.I26M | Missense Mutation (SNP) | VAF 39/270 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV53680552; called by muse, mutect2, varscan2
- GOLM2 | c.447G>T p.K149N | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV55463167; called by muse, mutect2, varscan2
- GPR162 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs1555119553; called by muse, mutect2, varscan2
- GPSM1 | c.1537C>A p.Q513K | Missense Mutation (SNP) | VAF 36/227 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs782438279; called by muse, mutect2, varscan2
- GRIN2B | c.2665G>A p.A889T | Missense Mutation (SNP) | VAF 37/281 reads (13%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.523); catalogued as rs756224637, COSV74208030; called by muse, mutect2, varscan2
- HCN1 | c.2074G>T p.A692S | Missense Mutation (SNP) | VAF 36/223 reads (16%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.03); catalogued as COSV100299639; called by muse, mutect2, varscan2
- HK3 | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 75/615 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373277952; called by muse, mutect2, varscan2
- HLA-A | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 100/702 reads (14%) | catalogued as rs199474400, COSV65142339; called by muse, mutect2, varscan2
- HTR1A | c.1189C>A p.P397T | Missense Mutation (SNP) | VAF 33/256 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60502922; called by muse, mutect2, varscan2
- IGLV3-25 | c.35C>T p.T12I | Missense Mutation (SNP) | VAF 20/191 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as rs1224635815; called by muse, varscan2
- IMPG1 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 32/214 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs1025950037; called by muse, mutect2, varscan2
- IRF4 | c.958G>C p.A320P | Missense Mutation (SNP) | VAF 55/303 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV66705378, COSV66705721; called by muse, mutect2, varscan2
- IRX4 | c.1387G>C p.A463P | Missense Mutation (SNP) | VAF 41/256 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs375480367; called by muse, mutect2, varscan2
- ITGA3 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 48/291 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs142527278, COSV50306912; called by muse, mutect2, varscan2
- KCNB2 | c.2044G>A p.G682S | Missense Mutation (SNP) | VAF 52/317 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs1204121504; called by muse, mutect2, varscan2
- KCNMB3 | c.831G>C p.E277D | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.188); catalogued as COSV99838756; called by muse, mutect2, varscan2
- KIAA0100 | c.709del p.Q237Rfs*11 | Frame Shift Del (DEL) | VAF 26/202 reads (13%) | catalogued as COSV66491398; called by mutect2, pindel, varscan2
- KIF26B | c.6095G>T p.R2032L | Missense Mutation (SNP) | VAF 55/253 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.706); catalogued as COSV63653739; called by muse, mutect2, varscan2
- LGI2 | c.110C>G p.P37R | Missense Mutation (SNP) | VAF 72/383 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1560296917; called by muse, varscan2
- LHCGR | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 62/400 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs979633619, COSV54295551, COSV54300568; called by muse, mutect2, varscan2
- MS4A14 | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 39/387 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.043); catalogued as COSV100280678; called by muse, mutect2, varscan2
- MUC19 | c.721G>T p.G241C | Missense Mutation (SNP) | VAF 32/220 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs1472193494, COSV101373683; called by muse, varscan2
- MYO5A | c.3007C>T p.R1003C | Missense Mutation (SNP) | VAF 61/327 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.339); catalogued as rs774132262; called by muse, mutect2, varscan2
- NPAS3 | c.1755C>A p.S585R (on ENST00000356141 / NM_001164749.2; = p.S553R on NM_022123.3) | Missense Mutation (SNP) | VAF 132/522 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.091); catalogued as rs1251249861; called by muse, mutect2, varscan2
- NUP98 | c.4421C>T p.S1474F (on ENST00000359171 / NM_001365126.1; = p.S1457F on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/400 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.257); catalogued as rs1188090731; called by muse, mutect2, varscan2
- OR2L13 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 50/393 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV63559039; called by muse, mutect2, varscan2
- OR52J3 | c.601G>T p.G201W | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100984915, COSV66747581; called by muse, mutect2, varscan2
- OTUB1 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT tolerated, low confidence (0.63); PolyPhen probably damaging (0.959); catalogued as rs1169307056, COSV100034206; called by muse, mutect2, varscan2
- PANK4 | c.1013A>G p.Y338C | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs377051516; called by muse, mutect2, varscan2
- PCDHA12 | c.240G>C p.Q80H | Missense Mutation (SNP) | VAF 135/880 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.881); catalogued as COSV56497961; called by muse, mutect2, varscan2
- PCDHB10 | c.2095G>A p.V699M | Missense Mutation (SNP) | VAF 93/677 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53379480, COSV53381191; called by muse, mutect2, varscan2
- PCDHGA11 | c.562G>T p.D188Y | Missense Mutation (SNP) | VAF 59/360 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.113); catalogued as rs756677817; called by muse, mutect2, varscan2
- PLCH1 | c.3970G>T p.D1324Y (on ENST00000340059 / NM_001130960.2; = p.D1316Y on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/353 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.087); catalogued as COSV58200364; called by muse, mutect2, varscan2
- PLCH1 | c.1345C>T p.H449Y (on ENST00000340059 / NM_001130960.2; = p.H461Y on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/293 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV58211122; called by muse, mutect2, varscan2
- PLPPR4 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV64566648, COSV64567265; called by muse, mutect2, varscan2
- PLXNB2 | c.3811G>A p.G1271S | Missense Mutation (SNP) | VAF 58/494 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as rs1383023136; called by muse, mutect2, varscan2
- PNMA8A | c.716C>G p.S239C | Missense Mutation (SNP) | VAF 46/316 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as rs746857338, COSV99047311; called by muse, mutect2, varscan2
- PPIE | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.156); catalogued as COSV100180253; called by muse, mutect2
- PRKDC | c.6721C>T p.L2241F | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as COSV58056980; called by muse, mutect2
- RABAC1 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 64/408 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55770972; called by muse, mutect2, varscan2
- RASGRP3 | c.2026G>C p.D676H (on ENST00000402538 / NM_001349975.2; = p.D675H on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.102); catalogued as rs773283474; called by muse, varscan2
- RET | c.2389G>C p.D797H | Missense Mutation (SNP) | VAF 79/488 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60690517; called by muse, mutect2, varscan2
- RND3 | c.182C>G p.T61R | Missense Mutation (SNP) | VAF 33/298 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV55724296; called by muse, mutect2, varscan2
- RNF43 | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 36/277 reads (13%) | catalogued as COSV68458045; called by muse, mutect2, varscan2
- RPS6KC1 | c.1187C>G p.S396C | Missense Mutation (SNP) | VAF 16/410 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as COSV65300401; called by muse, mutect2
- RRP1B | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 36/249 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs759504580; called by muse, mutect2, varscan2
- RYR1 | c.12602G>T p.R4201L | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.189); catalogued as COSV100614868; called by muse, mutect2, varscan2
- SCN7A | c.4304G>T p.G1435V | Missense Mutation (SNP) | VAF 30/304 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774533382; called by muse, mutect2
- SEH1L | c.1009C>G p.P337A | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs564759181, COSV50816168; called by muse, mutect2, varscan2
- SLC4A3 | c.395C>G p.A132G | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV56094864; called by muse, mutect2, varscan2
- SLC7A14 | c.113G>A p.G38E | Missense Mutation (SNP) | VAF 75/703 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.338); catalogued as rs138031691, COSV99200763; called by muse, mutect2, varscan2
- SLC9C2 | c.2866C>A p.R956S | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as COSV62944078, COSV62948312; called by muse, mutect2, varscan2
- SLFN11 | c.2020C>T p.R674C | Missense Mutation (SNP) | VAF 72/413 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.33); catalogued as rs201406101; called by muse, mutect2, varscan2
- SPATA31D1 | c.3988del p.E1330Rfs*11 | Frame Shift Del (DEL) | VAF 18/153 reads (12%) | catalogued as COSV100782541; called by mutect2, pindel, varscan2
- TCHH | c.1864C>A p.R622S | Missense Mutation (SNP) | VAF 121/515 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.072); catalogued as rs758469319; called by muse, mutect2, varscan2
- TECTB | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 41/261 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.018); catalogued as COSV101027713; called by muse, mutect2, varscan2
- TKFC | c.1074G>T p.Q358H | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs777577061; called by muse, mutect2, varscan2
- TLR10 | c.152C>T p.T51M | Missense Mutation (SNP) | VAF 50/241 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs375480992; called by muse, mutect2, varscan2
- TRPM3 | c.2244C>G p.H748Q (on ENST00000357533 / NM_001366142.2; = p.H591Q on NM_020952.6) | Missense Mutation (SNP) | VAF 48/275 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as COSV62589450, COSV62596748; called by muse, mutect2, varscan2
- TSEN54 | c.1300G>A p.D434N | Missense Mutation (SNP) | VAF 63/492 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV99390606; called by muse, mutect2, varscan2
- UBE4B | c.2794G>T p.A932S (on ENST00000343090 / NM_001105562.3; = p.A803S on NM_006048.5) | Missense Mutation (SNP) | VAF 57/315 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99477270; called by muse, mutect2, varscan2
- URI1 | c.838G>T p.G280C | Missense Mutation (SNP) | VAF 30/280 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100369058; called by muse, mutect2
- USH2A | c.3559G>T p.A1187S | Missense Mutation (SNP) | VAF 94/429 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs1460740827; called by muse, mutect2, varscan2
- ZFHX4 | c.79C>G p.L27V | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as rs749363037; called by muse, mutect2, varscan2
- ZNF506 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 44/363 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.568); catalogued as rs199847305, COSV71354177; called by muse, mutect2, varscan2
- ZNF737 | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 64/440 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); catalogued as rs1555756165; called by muse, varscan2
- ZNF804A | c.3547G>C p.A1183P | Missense Mutation (SNP) | VAF 37/240 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.227); catalogued as rs549778907; called by muse, mutect2, varscan2
- ZNF879 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 56/448 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); catalogued as rs781103881, COSV101469791; called by muse, mutect2, varscan2
- ABCC1 | c.2192A>T p.Q731L | Missense Mutation (SNP) | VAF 43/311 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- ABCC12 | c.27C>G p.I9M | Missense Mutation (SNP) | VAF 28/243 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AC100868.1 | c.1348G>C p.A450P | Missense Mutation (SNP) | VAF 15/178 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.082); called by muse, mutect2
- ACSM2A | c.716dup p.L240Pfs*16 (on ENST00000219054; = p.L161Pfs*16 on NM_001308169.2) | Frame Shift Ins (INS) | VAF 20/104 reads (19%) | called by mutect2, varscan2
- ADCY10 | c.508C>T p.Q170* | Nonsense Mutation (SNP) | VAF 43/401 reads (11%) | called by muse, mutect2, varscan2
- ALOX5 | c.1546T>A p.Y516N | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- ALX4 | c.608A>T p.E203V | Missense Mutation (SNP) | VAF 56/436 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ANKRD26 | c.134G>C p.R45P | Missense Mutation (SNP) | VAF 97/607 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- ANKRD30A | c.4005G>C p.Q1335H (on ENST00000611781; = p.Q1279H on NM_052997.2) | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- ANKRD30B | c.3782C>T p.S1261L | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANO8 | c.3274del p.V1092Wfs*227 | Frame Shift Del (DEL) | VAF 10/109 reads (9%) | called by mutect2, pindel
- ARMC3 | c.537G>T p.Q179H | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ASPA | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 33/264 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- ASPM | c.8030G>A p.R2677K | Missense Mutation (SNP) | VAF 52/376 reads (14%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ASTN1 | c.859A>T p.T287S | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ATP2B4 | c.2854C>G p.L952V | Missense Mutation (SNP) | VAF 50/409 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- B3GALNT1 | c.90C>G p.F30L | Missense Mutation (SNP) | VAF 25/348 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- B3GNT7 | c.289C>T p.H97Y | Missense Mutation (SNP) | VAF 39/322 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- BAHCC1 | c.2954C>A p.A985E | Missense Mutation (SNP) | VAF 40/228 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2771C>T p.S924L | Missense Mutation (SNP) | VAF 20/470 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2
- CADM2 | c.88C>A p.Q30K (on ENST00000407528 / NM_001167674.2; = p.Q32K on NM_153184.4) | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CALB1 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- CASZ1 | c.2275G>T p.E759* | Nonsense Mutation (SNP) | VAF 16/92 reads (17%) | called by muse, mutect2, varscan2
- CCNB1 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CCR6 | c.940G>C p.V314L | Missense Mutation (SNP) | VAF 48/388 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- CCT7 | c.1225G>C p.G409R | Missense Mutation (SNP) | VAF 56/203 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD248 | c.2229del p.R744Gfs*61 | Frame Shift Del (DEL) | VAF 28/180 reads (16%) | called by mutect2, varscan2
- CD6 | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.028); called by muse, mutect2
- CDH13 | c.2141G>C p.*714Sext*8 | Nonstop Mutation (SNP) | VAF 10/204 reads (5%) | called by muse, mutect2
- CDS2 | c.1030A>T p.T344S | Missense Mutation (SNP) | VAF 75/509 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CEBPD | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 78/446 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- CELSR1 | c.4297G>C p.G1433R | Missense Mutation (SNP) | VAF 41/363 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFTR | c.251A>T p.Y84F | Missense Mutation (SNP) | VAF 27/197 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CNFN | c.253T>C p.S85P | Missense Mutation (SNP) | VAF 38/281 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- COL4A4 | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COMP | c.1396G>A p.D466N | Missense Mutation (SNP) | VAF 107/586 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- CPNE3 | c.1364G>C p.G455A | Missense Mutation (SNP) | VAF 80/485 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD2 | c.1544-2A>T p.X515_splice | Splice Site (SNP) | VAF 13/74 reads (18%) | called by muse, varscan2
- CUBN | c.3638A>T p.E1213V | Missense Mutation (SNP) | VAF 49/384 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CWF19L1 | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 23/228 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- CXCR6 | c.80T>A p.L27Q | Missense Mutation (SNP) | VAF 43/252 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- CYTH4 | c.835C>A p.R279S | Missense Mutation (SNP) | VAF 21/214 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- DCAF8 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 39/268 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- DCHS1 | c.3622A>T p.S1208C | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- DDB2 | c.1177G>A p.G393S | Missense Mutation (SNP) | VAF 96/694 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DGKI | c.1621C>A p.L541M | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DHX57 | c.3793C>T p.H1265Y | Missense Mutation (SNP) | VAF 6/149 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); called by muse, mutect2
- DNAH3 | c.5435A>G p.K1812R | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DYSF | c.458-1G>C p.X153_splice | Splice Site (SNP) | VAF 59/470 reads (13%) | called by muse, mutect2, varscan2
- DZIP3 | c.2134G>T p.D712Y | Missense Mutation (SNP) | VAF 40/343 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EIF4A1 | c.1076+4A>G | Splice Region (SNP) | VAF 47/220 reads (21%) | called by muse, mutect2, varscan2
- EMID1 | c.613G>T p.G205W | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ERBB4 | c.3286G>C p.G1096R | Missense Mutation (SNP) | VAF 41/332 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- ETAA1 | c.1007C>G p.S336* | Nonsense Mutation (SNP) | VAF 23/148 reads (16%) | called by muse, mutect2, varscan2
- EVI2B | c.256T>C p.Y86H | Missense Mutation (SNP) | VAF 73/491 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- F2RL2 | c.892T>C p.W298R | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM122A | c.571A>G p.I191V | Missense Mutation (SNP) | VAF 41/271 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- FAM135B | c.2269G>T p.E757* | Nonsense Mutation (SNP) | VAF 57/224 reads (25%) | called by muse, mutect2, varscan2
- FAM25G | c.151A>T p.I51L | Missense Mutation (SNP) | VAF 26/608 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2
- FANCB | c.85A>G p.K29E | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FBXL19 | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBXO24 | c.82G>C p.E28Q (on ENST00000241071 / NM_033506.3; = p.E66Q on NM_012172.5) | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- FGFR1 | c.528C>G p.F176L (on ENST00000447712 / NM_023110.3; = p.F174L on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 301/701 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- FNDC1 | c.3317C>A p.S1106Y | Missense Mutation (SNP) | VAF 43/277 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FNIP1 | c.323C>G p.S108C | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- FRMD4A | c.1077dup p.K360Efs*20 | Frame Shift Ins (INS) | VAF 17/137 reads (12%) | called by mutect2, pindel, varscan2
- GABRA1 | c.1078C>A p.P360T | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.345); called by muse, mutect2
- GATA1 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 65/147 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- GOLGA8Q | c.318G>C p.Q106H | Missense Mutation (SNP) | VAF 40/311 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- GP2 | c.975C>G p.D325E (on ENST00000381362 / NM_001007240.3; = p.D322E on NM_001502.4) | Missense Mutation (SNP) | VAF 39/225 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GPR156 | c.34G>T p.D12Y | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- GREB1L | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 19/250 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- GRIN3A | c.1177A>T p.M393L | Missense Mutation (SNP) | VAF 42/264 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRM8 | c.1468C>A p.H490N | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- GTF3C1 | c.5498A>C p.Q1833P | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- GUCY2F | c.2311T>C p.Y771H | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- HDX | c.700G>T p.E234* | Nonsense Mutation (SNP) | VAF 32/136 reads (24%) | called by muse, mutect2, varscan2
- HECW1 | c.4792G>C p.E1598Q | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- HGF | c.1594G>T p.A532S | Missense Mutation (SNP) | VAF 27/272 reads (10%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HTR1A | c.233T>C p.L78S | Missense Mutation (SNP) | VAF 70/534 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHA2 | c.549G>C p.W183C | Missense Mutation (SNP) | VAF 72/312 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHV3OR16-9 | c.182C>A p.A61E | Missense Mutation (SNP) | VAF 83/554 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- IGKV2-24 | c.196G>T p.G66C | Missense Mutation (SNP) | VAF 58/394 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGSF1 | c.1199C>A p.T400N | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- IMPG1 | c.599C>A p.T200N | Missense Mutation (SNP) | VAF 44/248 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ITPR2 | c.5120A>T p.D1707V | Missense Mutation (SNP) | VAF 33/325 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.046); called by muse, mutect2
- IZUMO1 | c.541G>C p.D181H | Missense Mutation (SNP) | VAF 35/225 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- JRKL | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 3/34 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); called by muse, mutect2
- JUNB | c.94T>A p.Y32N | Missense Mutation (SNP) | VAF 40/295 reads (14%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- KCNK4 | c.1128G>T p.K376N | Missense Mutation (SNP) | VAF 39/291 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- KHDRBS1 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2, varscan2
- KIAA0408 | c.211A>G p.K71E | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.062); called by mutect2, varscan2
- KIF27 | c.3919_3924del p.S1307_S1308del | In Frame Del (DEL) | VAF 13/115 reads (11%) | called by mutect2, pindel, varscan2
- LAG3 | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 211/613 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- LGALS3BP | c.1495G>C p.D499H | Missense Mutation (SNP) | VAF 70/413 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- LILRB5 | c.1330A>G p.T444A (on ENST00000449561 / NM_001081442.3; = p.T443A on NM_006840.5) | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRTM4 | c.1289T>A p.V430E | Missense Mutation (SNP) | VAF 26/207 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- LRRTM4 | c.825C>A p.C275* | Nonsense Mutation (SNP) | VAF 16/106 reads (15%) | called by muse, mutect2, varscan2
- MALRD1 | c.3840C>A p.D1280E | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- MASP1 | c.494A>G p.Y165C | Missense Mutation (SNP) | VAF 81/730 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MBTPS2 | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- MGAT4D | c.505G>T p.V169L | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MGRN1 | c.673G>C p.E225Q | Missense Mutation (SNP) | VAF 8/238 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MICU2 | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MME | c.332G>C p.R111T | Missense Mutation (SNP) | VAF 36/305 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MNDA | c.68C>A p.T23K | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MON2 | c.2919G>A p.W973* | Nonsense Mutation (SNP) | VAF 16/112 reads (14%) | called by muse, mutect2, varscan2
- MTMR8 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC17 | c.4709A>T p.E1570V | Missense Mutation (SNP) | VAF 38/228 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- MUC19 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.145); called by muse, varscan2
- MYLIP | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 59/360 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- NANP | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 42/247 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- NBPF6 | c.1790A>C p.Q597P | Missense Mutation (SNP) | VAF 60/619 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- NES | c.1968A>T p.L656F | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- NR4A1 | c.94A>T p.K32* | Nonsense Mutation (SNP) | VAF 34/182 reads (19%) | called by muse, varscan2
- NRN1L | c.35G>T p.R12L | Missense Mutation (SNP) | VAF 132/707 reads (19%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- NXF3 | c.1507del p.Q503Rfs*7 | Frame Shift Del (DEL) | VAF 49/187 reads (26%) | called by mutect2, pindel, varscan2
- OR10A2 | c.433G>T p.V145L | Missense Mutation (SNP) | VAF 53/440 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- OR13G1 | c.460T>C p.W154R | Missense Mutation (SNP) | VAF 41/293 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- OR6Y1 | c.308T>A p.M103K | Missense Mutation (SNP) | VAF 58/385 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, varscan2
- OR8H3 | c.535T>A p.C179S | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PABPC3 | c.1730C>A p.T577N | Missense Mutation (SNP) | VAF 73/438 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHA3 | c.2116G>T p.A706S | Missense Mutation (SNP) | VAF 37/362 reads (10%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PCDHB14 | c.2308A>G p.I770V | Missense Mutation (SNP) | VAF 49/339 reads (14%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCDHGA9 | c.1528G>A p.D510N | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PDE1C | c.64del p.E22Nfs*13 | Frame Shift Del (DEL) | VAF 22/231 reads (10%) | called by mutect2, pindel, varscan2
- PDE3A | c.2666T>G p.L889R | Missense Mutation (SNP) | VAF 38/460 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PEA15 | c.74C>T p.S25L | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.299); called by muse, mutect2
- PFKP | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 35/271 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PHYKPL | c.99G>C p.K33N | Missense Mutation (SNP) | VAF 16/426 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PKD1L1 | c.3185G>T p.S1062I | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); called by mutect2, varscan2
- PKP4 | c.1246G>C p.E416Q | Missense Mutation (SNP) | VAF 68/497 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- PLCB1 | c.1031C>T p.S344F | Missense Mutation (SNP) | VAF 34/225 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PLCE1 | c.3955C>G p.L1319V | Missense Mutation (SNP) | VAF 19/660 reads (3%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.831); called by muse, mutect2
- POPDC3 | c.607G>T p.A203S | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POTEF | c.2439G>T p.K813N | Missense Mutation (SNP) | VAF 126/897 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- POU3F1 | c.665G>T p.G222V | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- POU3F1 | c.664G>T p.G222C | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- PPL | c.5156T>C p.F1719S | Missense Mutation (SNP) | VAF 39/268 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PRUNE2 | c.6953A>G p.D2318G | Missense Mutation (SNP) | VAF 47/247 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PSEN2 | c.456G>A p.M152I | Missense Mutation (SNP) | VAF 22/590 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.175); called by muse, mutect2
- PUS7 | c.1258A>T p.K420* | Nonsense Mutation (SNP) | VAF 17/86 reads (20%) | called by muse, mutect2, varscan2
- RAD54L2 | c.1021C>T p.Q341* | Nonsense Mutation (SNP) | VAF 26/137 reads (19%) | called by muse, mutect2, varscan2
- RB1CC1 | c.2300C>G p.S767* | Nonsense Mutation (SNP) | VAF 11/145 reads (8%) | called by muse, mutect2
- RBAK | c.517C>T p.H173Y | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- RBMX2 | c.629C>G p.S210* | Nonsense Mutation (SNP) | VAF 12/146 reads (8%) | called by muse, mutect2
- RFPL4AL1 | c.123G>T p.E41D | Missense Mutation (SNP) | VAF 120/812 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- RGS7 | c.838G>T p.A280S | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- RGS7 | c.240T>A p.H80Q | Missense Mutation (SNP) | VAF 43/407 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF148 | c.17T>C p.I6T | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF17 | c.200C>A p.T67N | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.001); called by muse, mutect2
- ROGDI | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 22/207 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RP1 | c.4222G>A p.A1408T | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RREB1 | c.4405del p.E1469Rfs*59 | Frame Shift Del (DEL) | VAF 23/178 reads (13%) | called by mutect2, pindel, varscan2
- RTKN | c.8C>A p.S3Y | Missense Mutation (SNP) | VAF 35/205 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- RUFY2 | c.1508A>T p.D503V | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- RYR1 | c.14542G>C p.V4848L | Missense Mutation (SNP) | VAF 117/600 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SAMD7 | c.520G>C p.E174Q | Missense Mutation (SNP) | VAF 37/313 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- SFI1 | c.1135C>A p.H379N | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SFPQ | c.706C>G p.R236G | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); called by muse, mutect2
- SHANK1 | c.836G>T p.R279L | Missense Mutation (SNP) | VAF 57/236 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SKI | c.597C>A p.C199* | Nonsense Mutation (SNP) | VAF 36/185 reads (19%) | called by muse, mutect2, varscan2
- SLC17A4 | c.725G>A p.C242Y | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SLC1A5 | c.26C>G p.S9C | Missense Mutation (SNP) | VAF 39/240 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- SLC35F1 | c.1094G>T p.R365L | Missense Mutation (SNP) | VAF 60/458 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- SLCO1A2 | c.1759G>T p.G587W | Missense Mutation (SNP) | VAF 25/277 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SMG1 | c.6671G>T p.R2224L | Missense Mutation (SNP) | VAF 42/274 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SPACA7 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- STIM1 | c.1991A>G p.E664G | Missense Mutation (SNP) | VAF 39/337 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- STT3A | c.1704G>T p.E568D | Missense Mutation (SNP) | VAF 32/264 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- SVEP1 | c.2613G>C p.W871C | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYNE1 | c.5306A>G p.Q1769R (on ENST00000367255 / NM_182961.4; = p.Q1776R on NM_033071.3) | Missense Mutation (SNP) | VAF 47/353 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- TASOR2 | c.6175A>G p.T2059A | Missense Mutation (SNP) | VAF 38/272 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBR1 | c.1558G>A p.G520S | Missense Mutation (SNP) | VAF 34/235 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM132D | c.1192C>A p.L398M | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TNNI3K | c.2505C>A p.S835R | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); called by muse, mutect2
- TRIM50 | c.447G>C p.K149N | Missense Mutation (SNP) | VAF 122/864 reads (14%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPM2 | c.2873A>T p.H958L | Missense Mutation (SNP) | VAF 44/285 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TTN | c.66427A>G p.T22143A (on ENST00000591111; = p.T14719A on NM_003319.4) | Missense Mutation (SNP) | VAF 5/51 reads (10%) | PolyPhen probably damaging (0.994); called by muse, mutect2
- UBQLN4 | c.1598A>T p.Q533L | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT tolerated (0.87); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- UNC80 | c.2624A>G p.D875G | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.995); called by muse, mutect2
- URI1 | c.839G>T p.G280V | Missense Mutation (SNP) | VAF 30/280 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); called by muse, mutect2
- WDR87 | c.4776G>C p.E1592D | Missense Mutation (SNP) | VAF 55/391 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- WDR87 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 41/294 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- XKR7 | c.1556A>T p.E519V | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ZFHX4 | c.5161C>T p.H1721Y | Missense Mutation (SNP) | VAF 35/271 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZFP28 | c.1057C>G p.Q353E | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- ZIC4 | c.821G>T p.C274F | Missense Mutation (SNP) | VAF 52/445 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- ZKSCAN3 | c.182G>T p.R61L | Missense Mutation (SNP) | VAF 50/358 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF354C | c.123G>A p.M41I | Missense Mutation (SNP) | VAF 54/280 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- ZNF473 | c.2110T>C p.C704R | Missense Mutation (SNP) | VAF 42/266 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF726 | c.1490C>A p.T497N | Missense Mutation (SNP) | VAF 62/530 reads (12%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ZNF727 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 16/71 reads (23%) | called by muse, varscan2
- ZNF841 | c.1201G>A p.E401K (on ENST00000426391 / NM_001369830.1; = p.E517K on NM_001136499.1 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- ZRANB3 | c.1641G>C p.E547D | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.118); called by muse, mutect2
- ABCC5 | c.4203C>G p.A1401= | Silent (SNP) | VAF 19/194 reads (10%) | catalogued as COSV55595578; called by muse, mutect2, varscan2
- ACSL3 | c.1002A>T p.L334= | Silent (SNP) | VAF 39/261 reads (15%) | called by muse, mutect2, varscan2
- AGK | c.285G>T p.V95= | Silent (SNP) | VAF 26/166 reads (16%) | called by muse, mutect2, varscan2
- APBA1 | c.1662C>T p.I554= | Silent (SNP) | VAF 25/155 reads (16%) | catalogued as rs146869320; called by muse, mutect2, varscan2
- ASPM | c.3531G>A p.V1177= | Silent (SNP) | VAF 82/548 reads (15%) | called by muse, mutect2, varscan2
- ATE1 | c.825G>A p.V275= | Silent (SNP) | VAF 22/178 reads (12%) | catalogued as rs1281468791; called by muse, mutect2, varscan2
- BACH2 | c.1125G>T p.G375= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs1434187899; called by muse, mutect2, varscan2
- BAHD1 | c.1872G>A p.E624= | Silent (SNP) | VAF 14/292 reads (5%) | called by muse, mutect2
- BRINP1 | c.1476G>T p.L492= | Silent (SNP) | VAF 53/239 reads (22%) | called by muse, mutect2, varscan2
- C1orf127 | c.1443G>A p.T481= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as rs568588607; called by muse, mutect2, varscan2
- C1orf35 | c.144C>T p.L48= | Silent (SNP) | VAF 47/313 reads (15%) | called by muse, mutect2, varscan2
- C2CD2L | c.1425C>T p.T475= | Silent (SNP) | VAF 15/152 reads (10%) | catalogued as rs781481883, COSV60884660; called by muse, mutect2, varscan2
- CASP5 | c.1080C>T p.F360= | Silent (SNP) | VAF 13/102 reads (13%) | called by muse, mutect2, varscan2
- CCDC168 | c.17538C>A p.T5846= | Silent (SNP) | VAF 35/206 reads (17%) | called by muse, mutect2, varscan2
- CDX2 | c.96C>G p.V32= | Silent (SNP) | VAF 55/238 reads (23%) | called by muse, mutect2, varscan2
- CMPK2 | c.1329G>A p.Q443= | Silent (SNP) | VAF 43/256 reads (17%) | catalogued as COSV99878733; called by muse, mutect2, varscan2
- COL3A1 | c.3870C>T p.I1290= | Silent (SNP) | VAF 19/146 reads (13%) | called by muse, mutect2, varscan2
- COL8A2 | c.390C>A p.L130= | Silent (SNP) | VAF 35/262 reads (13%) | called by muse, mutect2, varscan2
- CPXCR1 | c.561C>T p.F187= | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as rs1377535762, COSV52160801, COSV52163490; called by muse, mutect2, varscan2
- CRIP2 | c.216G>A p.A72= | Silent (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- CSMD1 | c.1863T>C p.S621= (on ENST00000520002; = p.S620= on NM_033225.6) | Silent (SNP) | VAF 53/260 reads (20%) | called by muse, mutect2, varscan2
- CYP7A1 | c.1089C>T p.I363= | Silent (SNP) | VAF 53/383 reads (14%) | called by muse, mutect2, varscan2
- DPY19L2 | c.1953A>T p.T651= | Silent (SNP) | VAF 25/259 reads (10%) | called by muse, mutect2, varscan2
- EFNB1 | c.450C>T p.G150= | Silent (SNP) | VAF 62/171 reads (36%) | catalogued as rs760426873, COSV52662992; called by muse, mutect2, varscan2
- EIF4B | c.1107A>T p.T369= | Silent (SNP) | VAF 18/194 reads (9%) | called by muse, mutect2
- ERAS | c.66G>A p.Q22= | Silent (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- FAM110C | c.435G>A p.K145= | Silent (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2
- FAM186A | c.3288G>A p.G1096= | Silent (SNP) | VAF 17/73 reads (23%) | called by muse, mutect2, varscan2
- FCRL3 | c.1221G>C p.L407= | Silent (SNP) | VAF 27/241 reads (11%) | catalogued as COSV100942692; called by muse, mutect2, varscan2
- FEZF1 | c.1056G>T p.G352= | Silent (SNP) | VAF 20/153 reads (13%) | catalogued as rs1309301194; called by muse, mutect2, varscan2
- FSHR | c.1215C>A p.A405= | Silent (SNP) | VAF 63/511 reads (12%) | called by muse, mutect2, varscan2
- GAB2 | c.579C>G p.L193= (on ENST00000361507 / NM_080491.3; = p.L155= on NM_012296.3) | Silent (SNP) | VAF 46/314 reads (15%) | called by muse, mutect2, varscan2
- GABRA1 | c.873C>A p.L291= | Silent (SNP) | VAF 52/360 reads (14%) | called by muse, mutect2, varscan2
- GAS2L1 | c.261C>T p.F87= | Silent (SNP) | VAF 7/163 reads (4%) | called by muse, mutect2
- GSN | c.168C>T p.H56= | Silent (SNP) | VAF 64/347 reads (18%) | called by muse, mutect2, varscan2
- GZF1 | c.1245C>G p.G415= | Silent (SNP) | VAF 51/379 reads (13%) | called by muse, mutect2, varscan2
- H2AC21 | c.51G>T p.S17= | Silent (SNP) | VAF 38/347 reads (11%) | called by muse, mutect2, varscan2
- HERC5 | c.84T>A p.S28= | Silent (SNP) | VAF 16/110 reads (15%) | called by muse, mutect2, varscan2
- HLX | c.522C>G p.L174= | Silent (SNP) | VAF 61/438 reads (14%) | catalogued as rs1411265262, COSV65044244; called by muse, mutect2, varscan2
- HRNR | c.2271G>A p.S757= | Silent (SNP) | VAF 180/674 reads (27%) | catalogued as rs374420054; called by muse, mutect2, varscan2
- IFNL2 | c.399C>A p.I133= | Silent (SNP) | VAF 36/230 reads (16%) | catalogued as COSV100122120; called by muse, mutect2, varscan2
- ITGA8 | c.3191G>A p.*1064= | Silent (SNP) | VAF 23/199 reads (12%) | catalogued as rs766800568; called by muse, mutect2, varscan2
- ITIH6 | c.3941G>A p.*1314= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as rs1292116006; called by muse, mutect2, varscan2
- KBTBD11 | c.1519C>T p.L507= | Silent (SNP) | VAF 14/113 reads (12%) | called by muse, mutect2, varscan2
- KCNA1 | c.471C>T p.F157= | Silent (SNP) | VAF 117/282 reads (41%) | catalogued as rs1310617367, COSV66836976; called by muse, mutect2, varscan2
- LAMA5 | c.2295G>A p.L765= | Silent (SNP) | VAF 11/96 reads (11%) | called by muse, mutect2, varscan2
- LENG8 | c.93G>T p.T31= | Silent (SNP) | VAF 28/206 reads (14%) | called by muse, mutect2, varscan2
- LILRA4 | c.1170G>T p.A390= | Silent (SNP) | VAF 91/956 reads (10%) | catalogued as COSV52490844; called by muse, varscan2
- LILRB1 | c.1731C>A p.A577= (on ENST00000427581; = p.A527= on NM_006669.6) | Silent (SNP) | VAF 20/193 reads (10%) | called by muse, mutect2, varscan2
- LRRC24 | c.25C>T p.L9= | Silent (SNP) | VAF 18/136 reads (13%) | called by muse, mutect2, varscan2
- LSMEM1 | c.390A>G p.Q130= | Silent (SNP) | VAF 17/76 reads (22%) | called by muse, mutect2, varscan2
- MAGEA3 | c.264C>T p.S88= | Silent (SNP) | VAF 69/242 reads (29%) | called by muse, mutect2, varscan2
- MAP4K2 | c.804G>T p.L268= | Silent (SNP) | VAF 63/438 reads (14%) | called by muse, mutect2, varscan2
- MARCHF11 | c.963G>T p.V321= | Silent (SNP) | VAF 48/295 reads (16%) | called by muse, mutect2, varscan2
- MGAT3 | c.624C>A p.V208= | Silent (SNP) | VAF 26/217 reads (12%) | called by muse, mutect2, varscan2
- MMP3 | c.585C>A p.A195= | Silent (SNP) | VAF 12/117 reads (10%) | called by muse, mutect2, varscan2
- MRTFB | c.1914C>T p.I638= | Silent (SNP) | VAF 59/336 reads (18%) | called by muse, mutect2, varscan2
- MTNR1A | c.63G>A p.A21= | Silent (SNP) | VAF 40/214 reads (19%) | called by muse, mutect2, varscan2
- MUC16 | c.1110C>T p.F370= | Silent (SNP) | VAF 24/260 reads (9%) | catalogued as rs774909794, COSV67484780; called by muse, mutect2
- MYPN | c.3414G>A p.Q1138= | Silent (SNP) | VAF 110/792 reads (14%) | catalogued as rs1400617342; called by muse, mutect2
- NAV3 | c.4344T>A p.S1448= | Silent (SNP) | VAF 33/255 reads (13%) | called by muse, mutect2, varscan2
- NCAM1 | c.2020C>T p.L674= (on ENST00000316851 / NM_181351.5; = p.L664= on NM_000615.7) | Silent (SNP) | VAF 29/240 reads (12%) | catalogued as COSV57514350; called by muse, mutect2, varscan2
- NDUFA9 | c.21C>T p.S7= | Silent (SNP) | VAF 48/486 reads (10%) | catalogued as rs745611828, COSV56932478; called by muse, mutect2
- NLGN1 | c.2169C>A p.T723= | Silent (SNP) | VAF 24/342 reads (7%) | called by muse, mutect2
- NLRP11 | c.684C>A p.L228= | Silent (SNP) | VAF 40/277 reads (14%) | catalogued as COSV64086431; called by muse, mutect2, varscan2
- NLRP5 | c.3033G>A p.T1011= | Silent (SNP) | VAF 43/318 reads (14%) | catalogued as rs187988999; called by muse, mutect2, varscan2
- NOTCH4 | c.5928G>A p.P1976= | Silent (SNP) | VAF 51/205 reads (25%) | catalogued as rs535015603; called by muse, mutect2, varscan2
- NPAP1 | c.843G>A p.L281= | Silent (SNP) | VAF 16/249 reads (6%) | called by muse, mutect2
- NUDCD2 | c.87C>T p.F29= | Silent (SNP) | VAF 20/224 reads (9%) | catalogued as rs988820400, COSV100243579; called by muse, mutect2
- NXF1 | c.945G>A p.L315= | Silent (SNP) | VAF 21/125 reads (17%) | catalogued as rs766998737, COSV53674684; called by muse, mutect2, varscan2
- OR11H1 | c.93C>T p.L31= | Silent (SNP) | VAF 54/1186 reads (5%) | catalogued as rs1406788276; called by muse, mutect2
- OR51E2 | c.636C>T p.F212= | Silent (SNP) | VAF 41/374 reads (11%) | catalogued as rs1363350527; called by muse, mutect2, varscan2
- OR52B4 | c.231G>C p.T77= | Silent (SNP) | VAF 26/167 reads (16%) | called by muse, mutect2, varscan2
- PCDHA11 | c.288C>T p.C96= | Silent (SNP) | VAF 110/766 reads (14%) | catalogued as COSV56479523; called by muse, mutect2, varscan2
- PCDHA13 | c.1857C>A p.R619= | Silent (SNP) | VAF 74/463 reads (16%) | called by muse, mutect2, varscan2
- PCDHB3 | c.2022G>T p.P674= | Silent (SNP) | VAF 95/649 reads (15%) | catalogued as rs373175296; called by muse, mutect2, varscan2
- PLCB1 | c.1128C>T p.I376= | Silent (SNP) | VAF 43/296 reads (15%) | catalogued as rs1450261335, COSV62042071; called by muse, varscan2
- PLXNA4 | c.3600C>G p.L1200= | Silent (SNP) | VAF 42/313 reads (13%) | called by muse, mutect2, varscan2
- PPFIA2 | c.585G>A p.L195= | Silent (SNP) | VAF 6/122 reads (5%) | catalogued as rs1350865415, COSV61048699; called by muse, mutect2
- PPP1R9A | c.1128A>G p.A376= | Silent (SNP) | VAF 31/232 reads (13%) | called by muse, mutect2, varscan2
- PRG4 | c.2394C>T p.A798= | Silent (SNP) | VAF 137/478 reads (29%) | catalogued as rs756146609, COSV63355908; called by muse, mutect2, varscan2
- PROZ | c.606C>T p.F202= | Silent (SNP) | VAF 20/131 reads (15%) | called by muse, mutect2, varscan2
- PTPRC | c.2433G>T p.V811= | Silent (SNP) | VAF 54/471 reads (11%) | called by muse, mutect2, varscan2
- RAI14 | c.2016A>T p.T672= | Silent (SNP) | VAF 25/156 reads (16%) | called by muse, mutect2, varscan2
- RBL2 | c.1248G>C p.V416= | Silent (SNP) | VAF 7/147 reads (5%) | catalogued as COSV50884086; called by muse, mutect2
- ROS1 | c.5166T>C p.Y1722= | Silent (SNP) | VAF 24/175 reads (14%) | called by muse, mutect2, varscan2
- ROS1 | c.1296T>C p.Y432= | Silent (SNP) | VAF 15/77 reads (19%) | called by mutect2, varscan2
- RTL1 | c.1908G>T p.L636= | Silent (SNP) | VAF 45/219 reads (21%) | called by muse, mutect2, varscan2
- RYR1 | c.11520C>A p.V3840= | Silent (SNP) | VAF 67/642 reads (10%) | catalogued as COSV100615798; called by muse, mutect2, varscan2
- RYR2 | c.12366A>T p.A4122= | Silent (SNP) | VAF 50/220 reads (23%) | called by muse, mutect2, varscan2
- SAMD8 | c.300C>T p.F100= | Silent (SNP) | VAF 20/113 reads (18%) | catalogued as COSV65509761; called by muse, mutect2, varscan2
- SGSM1 | c.2967G>C p.L989= (on ENST00000400359 / NM_001039948.4; = p.L928= on NM_133454.3) | Silent (SNP) | VAF 37/264 reads (14%) | called by muse, mutect2, varscan2
- SLC15A4 | c.534C>T p.F178= | Silent (SNP) | VAF 30/208 reads (14%) | called by muse, mutect2, varscan2
- SLC37A3 | c.573T>A p.I191= | Silent (SNP) | VAF 26/242 reads (11%) | called by muse, varscan2
- SMARCD2 | c.450G>T p.R150= | Silent (SNP) | VAF 22/138 reads (16%) | called by muse, mutect2, varscan2
- SPATA31E1 | c.3141C>G p.V1047= | Silent (SNP) | VAF 37/249 reads (15%) | called by muse, mutect2, varscan2
- SYP | c.447C>T p.F149= | Silent (SNP) | VAF 10/214 reads (5%) | catalogued as rs782728348; called by muse, mutect2
- TBX20 | c.219C>T p.S73= | Silent (SNP) | VAF 59/379 reads (16%) | catalogued as rs559991983; called by muse, mutect2, varscan2
- TCF7L1 | c.738C>T p.H246= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV56399337; called by muse, mutect2, varscan2
- TIGD3 | c.1110G>A p.T370= | Silent (SNP) | VAF 58/523 reads (11%) | catalogued as COSV52891074; called by muse, mutect2, varscan2
- TMEM248 | c.378C>T p.F126= | Silent (SNP) | VAF 72/404 reads (18%) | catalogued as rs186391366; called by muse, varscan2
- TSC1 | c.513C>T p.H171= | Silent (SNP) | VAF 69/430 reads (16%) | catalogued as rs377196837, COSV53764551; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- TTC27 | c.546A>G p.P182= | Silent (SNP) | VAF 29/143 reads (20%) | catalogued as rs201745073, COSV100512924; called by muse, mutect2, varscan2
- UGT1A9 | c.813C>T p.F271= | Silent (SNP) | VAF 23/180 reads (13%) | called by muse, mutect2, varscan2
- UNC80 | c.4800C>G p.L1600= | Silent (SNP) | VAF 19/113 reads (17%) | called by muse, mutect2, varscan2
- UPF3A | c.231G>C p.P77= | Silent (SNP) | VAF 71/484 reads (15%) | called by muse, mutect2, varscan2
- YEATS2 | c.981T>C p.V327= | Silent (SNP) | VAF 29/235 reads (12%) | called by muse, mutect2, varscan2
- ZNF160 | c.1638C>T p.F546= | Silent (SNP) | VAF 36/280 reads (13%) | called by muse, mutect2, varscan2
- ZNF425 | c.1095G>C p.R365= | Silent (SNP) | VAF 26/192 reads (14%) | called by muse, mutect2, varscan2
- ABCG4 | c.1168-82C>A | Intron (SNP) | VAF 22/151 reads (15%) | called by muse, mutect2, varscan2
- AC011487.2 | n.1075G>T | RNA (SNP) | VAF 68/370 reads (18%) | called by muse, mutect2, varscan2
- AC079612.1 | n.438G>C | RNA (SNP) | VAF 15/376 reads (4%) | called by muse, mutect2
- AC092118.1 | n.855G>C | RNA (SNP) | VAF 52/397 reads (13%) | called by muse, mutect2, varscan2
- ADAM15 | c.-39C>T | 5'UTR (SNP) | VAF 45/226 reads (20%) | catalogued as rs1199822496; called by muse, mutect2, varscan2
- ALKAL2 | c.-1G>A | 5'UTR (SNP) | VAF 12/65 reads (18%) | catalogued as rs1448119788; called by muse, mutect2
- ATP2B4 | c.3309+642C>T | Intron (SNP) | VAF 15/120 reads (13%) | called by muse, mutect2, varscan2
- ATP9B | c.558+1642G>A | Intron (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- BCAT2 | c.1140+39T>G | Intron (SNP) | VAF 27/152 reads (18%) | called by muse, mutect2, varscan2
- C10orf143 | c.69+3506C>T | Intron (SNP) | VAF 26/164 reads (16%) | called by muse, mutect2, varscan2
- CCNQP1 | n.242G>A | RNA (SNP) | VAF 145/600 reads (24%) | called by muse, mutect2, varscan2
- CDC45 | c.51+21C>T | Intron (SNP) | VAF 40/327 reads (12%) | catalogued as rs373683620; called by muse, mutect2, varscan2
- CIBAR1 | c.658-1853T>A | Intron (SNP) | VAF 29/158 reads (18%) | called by muse, mutect2, varscan2
- CLDN15 | c.217+531G>T | Intron (SNP) | VAF 35/307 reads (11%) | called by muse, mutect2, varscan2
- CLUHP11 | n.729C>G | RNA (SNP) | VAF 34/318 reads (11%) | called by muse, mutect2, varscan2
- COL11A1 | c.*40C>T | 3'UTR (SNP) | VAF 20/118 reads (17%) | catalogued as rs766361433; called by muse, mutect2, varscan2
- CTSLP8 | n.688G>A | RNA (SNP) | VAF 47/287 reads (16%) | called by muse, mutect2, varscan2
- CYBRD1 | c.193+436G>A | Intron (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- ELN | c.541+22G>C | Intron (SNP) | VAF 54/436 reads (12%) | called by muse, mutect2, varscan2
- FABP7 | c.348+64C>T | Intron (SNP) | VAF 21/199 reads (11%) | called by muse, mutect2, varscan2
- GATA3 | c.*8C>A | 3'UTR (SNP) | VAF 15/145 reads (10%) | called by muse, mutect2, varscan2
- HECTD4 | c.12047-155A>T | Intron (SNP) | VAF 16/78 reads (21%) | called by muse, varscan2
- IGFN1 | c.1242-406G>C | Intron (SNP) | VAF 13/448 reads (3%) | called by muse, mutect2
- KCTD7 | c.454-44C>T | Intron (SNP) | VAF 34/179 reads (19%) | called by muse, mutect2, varscan2
- KCTD7 | c.*41C>G | 3'UTR (SNP) | VAF 68/425 reads (16%) | called by muse, varscan2
- KRT8P11 | n.907C>T | RNA (SNP) | VAF 18/440 reads (4%) | called by muse, mutect2
- LHX9 | c.*2678C>A | 3'UTR (SNP) | VAF 22/127 reads (17%) | called by muse, mutect2, varscan2
- MECR | c.756+443A>T | Intron (SNP) | VAF 27/150 reads (18%) | called by muse, mutect2, varscan2
- MED17 | c.1744+33A>T | Intron (SNP) | VAF 61/489 reads (12%) | catalogued as COSV52601180; called by muse, mutect2, varscan2
- MEIS3 | c.*38C>A | 3'UTR (SNP) | VAF 19/150 reads (13%) | called by muse, mutect2
- MYL7 | c.377+45G>A | Intron (SNP) | VAF 39/207 reads (19%) | called by muse, mutect2, varscan2
- PLEC | c.524-763C>T | Intron (SNP) | VAF 86/709 reads (12%) | called by muse, mutect2, varscan2
- RADIL | c.2291-47A>T | Intron (SNP) | VAF 67/425 reads (16%) | called by muse, mutect2, varscan2
- RBMY2FP | n.287C>G | RNA (SNP) | VAF 40/147 reads (27%) | called by muse, mutect2, varscan2
- RHEB | c.-20_-6del | 5'UTR (DEL) | VAF 32/240 reads (13%) | called by mutect2, pindel
- RNF103 | c.-970C>G | 5'UTR (SNP) | VAF 32/277 reads (12%) | called by muse, mutect2, varscan2
- ROBO3 | c.2780-50C>A | Intron (SNP) | VAF 55/390 reads (14%) | called by muse, mutect2, varscan2
- SCAF11 | c.-21-10015T>A | Intron (SNP) | VAF 9/95 reads (9%) | called by muse, mutect2
- SCFD1 | c.-16G>C | 5'UTR (SNP) | VAF 30/148 reads (20%) | catalogued as rs570580164; called by muse, varscan2
- SCN1A | c.4853-40G>T | Intron (SNP) | VAF 21/170 reads (12%) | catalogued as rs1217462449; called by muse, mutect2, varscan2
- SDHAP2 | n.1147C>T | RNA (SNP) | VAF 34/598 reads (6%) | called by muse, mutect2
- SEPTIN2 | c.217+153A>T | Intron (SNP) | VAF 19/166 reads (11%) | called by muse, mutect2, varscan2
- SERTAD4 | c.-18+897A>C | Intron (SNP) | VAF 60/239 reads (25%) | called by muse, mutect2, varscan2
- SHANK1 | c.-2C>G | 5'UTR (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2, varscan2
- SPINDOC | c.934+3849G>A | Intron (SNP) | VAF 19/168 reads (11%) | called by muse, mutect2, varscan2
- ST8SIA3 | c.-41G>T | 5'UTR (SNP) | VAF 80/459 reads (17%) | called by muse, mutect2, varscan2
- TCN2 | c.*47C>G | 3'UTR (SNP) | VAF 43/305 reads (14%) | called by muse, mutect2, varscan2
- TM6SF1 | c.92+32G>C | Intron (SNP) | VAF 31/167 reads (19%) | called by muse, mutect2, varscan2
- TMEM75 | n.984T>C | RNA (SNP) | VAF 74/281 reads (26%) | called by muse, mutect2, varscan2
- TNIK | c.3859+82G>C | Intron (SNP) | VAF 23/206 reads (11%) | called by muse, mutect2, varscan2
- TNNT2 | c.200-25G>A | Intron (SNP) | VAF 143/632 reads (23%) | called by muse, mutect2, varscan2
- TRAPPC12 | c.1677+2621C>T | Intron (SNP) | VAF 36/184 reads (20%) | called by muse, mutect2, varscan2
- TTN | c.10360+1552C>T | Intron (SNP) | VAF 15/92 reads (16%) | called by muse, mutect2, varscan2
- TXLNGY | n.30G>C | RNA (SNP) | VAF 52/164 reads (32%) | called by muse, mutect2, varscan2
- UBE2M | c.-27G>A | 5'UTR (SNP) | VAF 42/166 reads (25%) | called by muse, mutect2, varscan2
- Y_RNA | chr7:75516114 T>C | 5'Flank (SNP) | VAF 44/360 reads (12%) | called by muse, mutect2, varscan2
- ZDHHC11 | c.784+162A>T | Intron (SNP) | VAF 24/288 reads (8%) | called by muse, mutect2
- ZEB2 | c.73+4956G>T | Intron (SNP) | VAF 37/280 reads (13%) | called by muse, mutect2, varscan2
- ZNF160 | c.271+697G>A | Intron (SNP) | VAF 18/299 reads (6%) | called by muse, mutect2
- ZNF177 | c.33+24C>G | Intron (SNP) | VAF 20/159 reads (13%) | catalogued as rs1188368524; called by muse, mutect2, varscan2
- ZNF461 | c.*849C>A | 3'UTR (SNP) | VAF 13/73 reads (18%) | called by muse, mutect2, varscan2
